CCDI case PBCBGY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/7ec85b8d-442a-4e93-a890-f08d451acc83

Demographics
Sex at birth: female; Race: black or african american; Vital status: Dead.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 22.6 years (8,252 days).

Biospecimens (3 samples)
- Sample 0DN9EG: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DN9EO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DN9EW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
